CCDI case PBCPBB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/526e8c5c-e48f-43d1-8ed9-a96627eed22d

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Neoplasm, metastatic: ICD-O-3 morphology code: 8000/6; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.8 years (1,015 days).

Biospecimens (3 samples)
- Sample 0DWWMC: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWWMK: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DWWN3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
